Somatic mutation profile of tumor specimen TCGA-17-Z044-01A (aliquot TCGA-17-Z044-01A-01W-0746-08) from TCGA case TCGA-17-Z044, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z044-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b42ab2e1-8902-4842-ae17-8ac156a8aaf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z044-11A (Solid Tissue Normal), aliquot TCGA-17-Z044-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0604fe41-2ade-4a62-add8-b8888508de8f

The open-access MAF lists 133 somatic variants for this specimen: 88 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 40, Nonsense Mutation 9, Frame Shift Del 5, RNA 4, Splice Region 2, Splice Site 2, Intron 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.8651C>G p.P2884R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV54954951; called by muse, mutect2, varscan2
- APBA2 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV101382079; called by muse, mutect2, varscan2
- BPIFA2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV53612579; called by muse, mutect2, varscan2
- CATSPER2 | c.1122G>A p.R374= | Splice Region (SNP) | VAF 28/103 reads (27%) | catalogued as rs1395866503, COSV99051792; called by muse, mutect2, varscan2
- CENPA | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51983102, COSV51983585; called by muse, mutect2, varscan2
- CHAT | c.434C>G p.T145R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.142); catalogued as rs766040346, COSV60329559; called by muse, mutect2, varscan2
- DAPK1 | c.2617G>T p.G873C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs368259645; called by muse, mutect2, varscan2
- DISP3 | c.1448G>C p.C483S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.908); catalogued as COSV53828176; called by muse, mutect2, varscan2
- FBXL14 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1297732566; called by muse, mutect2, varscan2
- FCRL2 | c.1513G>T p.V505L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV63835166; called by muse, mutect2
- GTDC1 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs750178969; called by muse, mutect2, varscan2
- HECW2 | c.4436G>T p.R1479L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs143511416, COSV53659825; called by muse, mutect2, varscan2
- HJURP | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV64978628; called by muse, mutect2, varscan2
- IGSF1 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV63837855; called by muse, mutect2, varscan2
- IL1RL1 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1183545961; called by muse, mutect2, varscan2
- KIAA0895 | c.1270C>T p.R424W (on ENST00000297063 / NM_001100425.2; = p.R373W on NM_015314.3) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767800476; called by muse, mutect2, varscan2
- KLF11 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755960649, COSV59940281; called by muse, mutect2, varscan2
- KRT73 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs774100736; called by muse, mutect2, varscan2
- LPCAT4 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775933812; called by muse, mutect2, varscan2
- LRFN5 | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53264255; called by muse, mutect2, varscan2
- LRRC66 | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV58633213; called by muse, mutect2, varscan2
- MRGPRF | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1415019897; called by muse, mutect2, varscan2
- MTTP | c.1909T>C p.Y637H | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286177740; called by muse, mutect2, varscan2
- NF1 | c.1642-2A>T p.X548_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as CS031798, COSV62206192; called by muse, mutect2, varscan2
- ODF2L | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1465374804; called by mutect2, varscan2
- PDHX | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746240660; called by muse, mutect2, varscan2
- PIGX | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs369166918; called by muse, mutect2, varscan2
- PRAMEF12 | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100743183; called by muse, mutect2, varscan2
- PTPRN2 | c.1788G>T p.S596= | Splice Region (SNP) | VAF 38/142 reads (27%) | catalogued as COSV67051620; called by muse, mutect2, varscan2
- RIT1 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 168/311 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64166614; called by muse, mutect2, varscan2
- ROBO4 | c.2093T>A p.L698Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as COSV99073936; called by muse, mutect2, varscan2
- RPIA | c.527+1del | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as COSV52168661; called by mutect2, pindel, varscan2
- SLC26A4 | c.603G>T p.L201F | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as rs1344890266, COSV55914188, COSV99707483; called by muse, mutect2, varscan2
- TAS2R38 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1554444409; called by muse, mutect2, varscan2
- TNIP1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV59304186; called by muse, mutect2
- WEE2 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs376644027; called by muse, mutect2, varscan2
- ZNF202 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 60/84 reads (71%) | catalogued as rs766606319; called by muse, mutect2, varscan2
- ZNF208 | c.3073G>T p.G1025* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as COSV68108263; called by muse, mutect2, varscan2
- ABHD17B | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2
- ADGRG6 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ADGRV1 | c.857del p.G286Efs*8 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | called by mutect2, pindel, varscan2
- ANK2 | c.5053G>T p.D1685Y | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- APOB | c.10106C>A p.S3369* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- AZGP1 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BSN | c.4551G>T p.M1517I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- CHD7 | c.4199G>A p.C1400Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHGB | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.749); called by muse, varscan2
- COL14A1 | c.1153G>C p.V385L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DGKD | c.2281A>C p.K761Q (on ENST00000264057 / NM_152879.3; = p.K717Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DNAH11 | c.12841T>A p.Y4281N | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH3 | c.4238+2T>C p.X1413_splice | Splice Site (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- EFCAB12 | c.1517G>A p.W506* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- FLI1 | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FTSJ3 | c.980del p.A327Efs*42 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- GPR65 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- HERC6 | c.2533A>G p.I845V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HSP90AA1 | c.55A>T p.T19S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGKV1-17 | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV3-15 | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ITGAE | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- KCNV1 | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCE1B | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 91/143 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LCE4A | c.150C>A p.C50* | Nonsense Mutation (SNP) | VAF 144/201 reads (72%) | called by muse, mutect2, varscan2
- NFATC4 | c.1397T>C p.M466T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- NUP37 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 49/85 reads (58%) | called by muse, mutect2, varscan2
- OR10G4 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- OR11H4 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR52E8 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- OR5B12 | c.231_232delinsG p.K78Rfs*2 | Frame Shift Del (DEL) | VAF 30/119 reads (25%) | called by pindel, varscan2*
- OR5T2 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PAK6 | c.1853dup p.P619Tfs*47 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- PDK2 | c.379_381dup p.V127dup | In Frame Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- RAD18 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- S100A4 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SERPINB11 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 122/211 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SLC17A1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMCO3 | c.31del p.V11Cfs*22 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | called by mutect2, pindel, varscan2
- TMCO4 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TMF1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC93A | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 43/73 reads (59%) | called by muse, mutect2, varscan2
- USP29 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR64 | c.3154C>A p.R1052S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ZAN | c.4390C>A p.P1464T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ZBTB20 | c.1336A>T p.I446F (on ENST00000474710 / NM_001164342.2; = p.I373F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZIM2 | c.756T>A p.D252E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF804A | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRL3 | c.3684T>A p.S1228= (on ENST00000506720 / NM_001322402.2; = p.S1160= on NM_015236.6) | Silent (SNP) | VAF 38/128 reads (30%) | called by muse, mutect2, varscan2
- APOB | c.12480C>T p.G4160= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.1542A>G p.A514= (on ENST00000398564; = p.A489= on NM_014629.4) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs777301616; called by muse, mutect2, varscan2
- ARHGEF25 | c.1623G>A p.L541= | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- ASNSD1 | c.186C>G p.T62= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- CDH13 | c.540G>A p.V180= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, varscan2
- DBR1 | c.612A>T p.T204= | Silent (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
- DEFA3 | c.267C>G p.L89= | Silent (SNP) | VAF 26/54 reads (48%) | called by mutect2, varscan2
- FPR1 | c.135G>C p.G45= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- FSCB | c.1125T>A p.S375= | Silent (SNP) | VAF 91/232 reads (39%) | called by muse, mutect2, varscan2
- FYB1 | c.1257A>G p.L419= | Silent (SNP) | VAF 202/532 reads (38%) | called by muse, mutect2, varscan2
- GJB5 | c.504A>G p.P168= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, varscan2
- GJB5 | c.543A>G p.S181= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, varscan2
- GLI3 | c.3678A>T p.P1226= | Silent (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- IK | c.894T>G p.L298= | Silent (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- IQCH | c.1605C>T p.I535= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- IRS4 | c.2262T>C p.P754= | Silent (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- KCNA6 | c.27G>A p.L9= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- KMT2C | c.2412T>A p.L804= | Silent (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- KRTAP13-2 | c.204G>C p.T68= | Silent (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- LCTL | c.807C>T p.D269= | Silent (SNP) | VAF 70/172 reads (41%) | catalogued as rs1367701402; called by muse, mutect2, varscan2
- MYH3 | c.3423C>A p.A1141= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- OPRM1 | c.747C>T p.I249= | Silent (SNP) | VAF 65/104 reads (63%) | catalogued as rs768747134; called by muse, mutect2, varscan2
- OR2B2 | c.552G>A p.L184= | Silent (SNP) | VAF 116/244 reads (48%) | called by muse, mutect2, varscan2
- OR5D18 | c.36G>T p.T12= | Silent (SNP) | VAF 68/110 reads (62%) | catalogued as rs770192032; called by muse, mutect2, varscan2
- OR5D18 | c.696C>T p.V232= | Silent (SNP) | VAF 79/120 reads (66%) | catalogued as COSV61737108, COSV61738898; called by muse, mutect2, varscan2
- OTOGL | c.988C>T p.L330= (on ENST00000547103; = p.L321= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 81/132 reads (61%) | called by muse, mutect2, varscan2
- PCDHB11 | c.1332C>A p.V444= | Silent (SNP) | VAF 61/139 reads (44%) | called by muse, mutect2, varscan2
- PKP2 | c.2130G>T p.T710= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as rs371089832, COSV50726459; ClinVar: likely benign; called by muse, mutect2, varscan2
- PUM3 | c.1326A>G p.L442= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs749127582; called by muse, mutect2, varscan2
- RUNX1T1 | c.1467G>T p.T489= (on ENST00000265814 / NM_001198628.1; = p.T462= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV56138343; called by muse, mutect2, varscan2
- SERAC1 | c.1002T>C p.S334= | Silent (SNP) | VAF 35/61 reads (57%) | called by mutect2, varscan2
- SORCS1 | c.1617G>T p.G539= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.3627C>G p.L1209= | Silent (SNP) | VAF 12/73 reads (16%) | called by mutect2, varscan2
- STT3A | c.1410C>G p.T470= | Silent (SNP) | VAF 82/153 reads (54%) | called by muse, mutect2, varscan2
- TGIF2LX | c.471G>T p.L157= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV52213400; called by muse, mutect2, varscan2
- TOE1 | c.306C>T p.L102= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1174448118, COSV100516937; called by muse, mutect2, varscan2
- USP33 | c.1710A>G p.Q570= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- ZNF704 | c.603G>C p.G201= | Silent (SNP) | VAF 38/59 reads (64%) | called by muse, mutect2, varscan2
- ZNF721 | c.1395A>G p.Q465= (on ENST00000338977; = p.Q477= on NM_133474.4) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs782365908; called by muse, mutect2, varscan2
- MIR519C | n.30G>T | RNA (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- RUSC1 | c.-86-258C>T | Intron (SNP) | VAF 11/37 reads (30%) | catalogued as rs1247142131; called by muse, mutect2, varscan2
- SLC22A17 | n.881C>T | RNA (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- SNORD114-17 | n.71T>G | RNA (SNP) | VAF 34/55 reads (62%) | called by muse, mutect2, varscan2
- SNORD114-17 | n.72C>T | RNA (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
